Gene-level copy-number profile of tumor specimen TCGA-H7-A6C5-01A from TCGA case TCGA-H7-A6C5, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.2 years (23,808 days).
Specimen TCGA-H7-A6C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a42cb29c-9cc4-4d5c-a525-56f1d1c657ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-H7-A6C5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3b4ba53-a5d8-4fc4-8ac4-024e45b5ba7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,212; copy number 2: 45,806; copy number 3: 1,654; copy number 4: 43; copy number 5: 83; copy number 6: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-H7-A6C5-01A-11D-A30D-01): tumor purity 0.58, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 104 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,507,058–248,919,946, 83 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr22:16,601,887–16,698,742, 1 gene, copy number 6 (within-gene range 3–6): TPTEP1.
- chr22:16,653,892–16,922,173, 20 genes, copy number 6: PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3.

Autosomal genes at a single copy (total copy number 1): 11,077. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
